Surgical pathology report (de-identified scan), TCGA case TCGA-CN-4725, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-4725-01A (Primary Tumor).

[page 1 of 5]
PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Squamous cell carcinoma of right tongue.

PROCEDURE: Right neck dissection.

SPECIFIC CLINICAL QUESTION: Check margin.

OUTSIDE TISSUE DIAGNOSIS: Yes, squamous cell carcinoma.

PRIOR MALIGNANCY: No.

CHEMORADIATION THERAPY: No.

ORGAN TRANSPLANT: No.

IMMUNOSUPPRESSION: No.

OTHER DISEASES: No.

[REDACTED]

FINAL DIAGNOSIS:

PART 1: TONGUE, RIGHT LATERAL, PARTIAL GLOSSECTOMY --

- A. INVASIVE SQUAMOUS CELL CARCINOMA, KERATINIZING, MODERATELY DIFFERENTIATED (2.8 CM, 0.6 CM THICK), INFILTRATIVE BORDER
- B. FOCAL PERINEURAL INVASION PRESENT.
- C. NO ANGIOLYMPHATIC INVASION.
- D. MARGINS FREE OF TUMOR (SEE ALSO PARTS 2 THROUGH 4).
- E. PATHOLOGIC STAGE: pT2, N0.

PART 2: TONGUE, MEDIAL, EXCISION --
NO TUMOR PRESENT.

PART 3: TONGUE, LATERAL, AND FLOOR OF MOUTH, EXCISION --
NO TUMOR PRESENT.

PART 4: SOFT TISSUE, DEEP MARGIN, EXCISION --
NO TUMOR PRESENT.

PART 5: LYMPH NODES, RIGHT NECK LEVEL 1, SELECTIVE DISSECTION --
A. FOUR LYMPH NODES, NO TUMOR PRESENT (0/4).
B. SUBMANDIBULAR GLAND WITH CHRONIC SIALADENITIS.

PART 6: LYMPH NODES, RIGHT NECK LEVELS 3 AND 4, SELECTIVE DISSECTION --
EIGHT LYMPH NODES, NO TUMOR PRESENT (0/8).

PART 7: LYMPH NODES, RIGHT NECK LEVEL 2B, SELECTIVE DISSECTION --
ONE LYMPH NODE, NO TUMOR PRESENT (0/1).

PART 8: LYMPH NODES, RIGHT NECK LEVEL 2, SELECTIVE DISSECTION --
THREE LYMPH NODES, NO TUMOR PRESENT (0/3).

[REDACTED]

[page 2 of 5]
Pathology Report

COMMENT:

Ancillary studies will be performed and reported as an addendum.

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in seven parts.

Part 1 is labeled with the patient's name, medical record number, initials [REDACTED] and "right lateral tongue, stitch anterior". It consists of a partial glossectomy, 3.4 x 2.5 x 0.9 cm. There is a 2.8 x 2.1 x 0.6 cm ulcerated raised, well-circumscribed, firm mass. It is 0.7 cm from the posterior margin, 0.6 cm from inferior margin, 0.5 cm from superior margin, and 0.3 cm from anterior margin. On cross section, the tumor is 0.4 cm from the deep margin. Anterior margin is inked black and the posterior margin is inked green. Other margins are sampled in Parts 2 through 4. Representative tumor is banked for [REDACTED] Banked area is inked red. Representative midline cross section, including radial anterior, deep and posterior margin is taken for frozen section.

Section code:

1AFS- representative midline cross section, frozen section

1B-E- remainder of specimen serially cross sectioned

Dictated by [REDACTED]

Part 2 is labeled with the patient's name, initials [REDACTED] and "medial tongue, stitch anterior". It consists of a strip of tan-pink wrinkled mucosa with underlying pink-red cauterized soft tissue 4.5 x 0.4 x 0.3 cm. Stitch marks anterior. The anterior resection margin (site of stitch) is inked with blue dye. The entire specimen is submitted for intraoperative frozen section consultation. The remaining frozen section tissue is submitted labeled 2AFS.

Part 3 is labeled with the patient's name, initials [REDACTED] and "floor of mouth lateral tongue". It consists of two portions of tan-pink, focally cauterized, soft tissue 0.6 x 0.4 x 0.3 cm and 2.4 x 0.5 x 0.3 cm respectively. After intraoperative frozen section consultation the tissue is submitted labeled 3AFS.

Part 4 is labeled with the patient's name, initials [REDACTED] and "deep margin". It consists of a portion of pink-red, roughened, cauterized, soft tissue 2.0 x 0.5 x 0.4 cm. After intraoperative frozen section consultation the tissue is submitted labeled 4AFS.

Part 5 is labeled with the patient's name, initials [REDACTED] and "right neck level I". It consists of soft yellow-red lobular fibroadipose tissue with a partially embedded submandibular gland 8.0 x 4.0 x 1.3 cm in overall dimensions.

The submandibular gland is grossly intact, ovoid pale yellow to tan and lobular 4.0 x 2.2 x 1.2 cm. No gross suspicious lesions are identified.

Occasional ovoid soft tan-pink lymph nodes ranging 0.3 to 0.6 cm in greatest dimension are identified within the fibrofatty tissue.

Section code:

5A- submandibular gland, representative section

5B- intact lymph node

[page 3 of 5]
Pathology Report

Part 6 is labeled with the patient's name, initials [REDACTED] and "right neck level III and IV". It consists of a fragment portion of soft, yellow-red, lobular fibroadipose tissue 8.0 x 3.4 x 0.7 cm. The specimen is divided into halves and on dissection multiple ovoid soft tan-pink lymph nodes ranging 0.2 to 1.3 cm in greatest dimension are identified.

Section code:

6A-lymph nodes one half of specimen

6B- lymph nodes remaining half of specimen

Part 7 is labeled with the patient's name, initials [REDACTED] and "right neck level IIB". It consists of a 2.7 x 2.3 x 0.5 cm portion of soft, yellow-red, lobular, focally cauterized fibroadipose tissue containing two soft pink lymph nodes each 0.2 cm in greatest dimension.

Section code:

7A- lymph nodes (2)

Part 8 is labeled with the patient's name, initials [REDACTED] "right level II". It consists of a 3.3 x 3.3 x 0.9 cm portion of soft, yellow-red, lobular, focally cauterized fibroadipose tissue containing three ovoid tan-pink soft lymph nodes 0.3, 1.5 x 1.6 cm in greatest dimension respectively.

Section code:

8A- intact lymph nodes (2)

8B- intact lymph node (1)

GROSSED BY [REDACTED]

INTRAOPERATIVE CONSULTATION:

1A: RIGHT LATERAL TONGUE, RADIAL ANTERIOR (BLACK), AND POSTERIOR (GREEN) MARGINS (frozen section) --

- A. MALIGNANT.
- B. SQUAMOUS CELL CARCINOMA.
- C. DEEP AND POSTERIOR MARGINS ARE FREE OF CARCINOMA, CARCINOMA IS 0.2 CM FROM ANTERIOR MARGIN

2A: MEDIAL TONGUE (frozen section) --

- A. BENIGN.
- B. NO TUMOR SEEN [REDACTED]

3A: FLOOR OF MOUTH (frozen section) --

- A. BENIGN.
- B. NO TUMOR SEEN [REDACTED]

4A: DEEP MARGIN (frozen section) --

- A. BENIGN.
- B. NO TUMOR SEEN [REDACTED]

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, insitu hybridization (ISH & FISH), molecular anatomic pathology, and immunofluorescence testing:

The testing was developed and its performance characteristics determined by the [REDACTED] Department of Pathology, as

[page 4 of 5]
Pathology Report

required by the [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of [REDACTED] to a maximum of [REDACTED].

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND TUMORS

SPECIMEN TYPE:	Resection: PARTIAL GLOSSECTOMY
TUMOR SITE:	Oral Cavity
TUMOR SIZE:	Greatest dimension: 2.8 cm Additional dimensions: 0.6 THICK cm
HISTOLOGIC TYPE:	Squamous cell carcinoma, conventional
HISTOLOGIC GRADE:	G2
PRIMARY TUMOR (pT):	pT2
REGIONAL LYMPH NODES (pN):	pN0 Number of regional lymph nodes examined: 16 Number of regional lymph nodes involved: 0
DISTANT METASTASIS (pM):	pMX
MARGINS:	Margins uninvolved by tumor
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):	Absent
PERINEURAL INVASION:	Present

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Right Lateral Tongue, Stitch Anterior

Taken:	[REDACTED]
Stain/cnt	Block
H&E x 1	B
H&E x 1	C
H&E Recut x 1	D
IHPV x 1	D
cmst x 1	D
IEGFR x 1	D
IBNKNK x 1	D
IBNKNK x 1	D
IBNKNK x 1	D
IBNKNK x 1	D
IBNKNK x 1	D
IBNKNK x 1	D
H&E x 1	D
P16 x 1	D
V-EGFR x 1	D
H&E x 1	E
H&E x 1	AFS

Part 2: Medial tongue, Stitch Anterior

Taken [REDACTED]

[page 5 of 5]
Pathology Report

Stain/cnt Block
H&E x 1 AFS

Part 3: Floor of Mouth, Lateral Tongue

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 AFS

Part 4: Deep Margin

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 AFS

Part 5: Right Neck Level 1

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 A
H&E x 1 B

Part 6: Right Neck Level 3 and 4

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 A
H&E x 1 B

Part 7: Right Neck Level 2B

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 A

Part 8: Right Level 2

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 A
H&E x 1 B

ICD-9 Diagnosis Codes: (None Entered)

Source: NCI Genomic Data Commons file be95ecc1-136c-47c7-b227-6eb1c465ebbf (TCGA-CN-4725.4E698BD3-EBD0-4630-8F7D-C10A1011BD66.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).